Surgical pathology report (de-identified scan), TCGA case TCGA-44-2668, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-2668-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN

- A. Right upper lobe FS procurement
- B. Right middle lobe nodule
- C. Node level 11
- D. Node 4R
- E. 2R Fat pads
- F. Node level 7

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung nodule.

FROZEN SECTION DIAGNOSIS

Lung, right upper lobe, resection: Non small cell carcinoma.
Bronchial margin negative for carcinoma.

GROSS DESCRIPTION

- A. The specimen is received unfixed labeled "right upper lobe" and consists of a red lung lobe weighing 375 gm and measuring 15.5 x 14 x 4.5 cm. The pleural surface has a puckered appearance over a white solid mass measuring 3.7 x 2.4 x approximately 2.4 cm. A portion of tumor is taken for research purposes. A portion of tumor is taken for frozen section diagnosis.
- A portion of the bronchial margin is also taken for frozen section diagnosis. Additional sections after fixation. RS-9
- B. Received in formalin labeled "right middle lung lobe nodule" and consists of a tan piece of tissue with stapled margins. The stapled edge measures 3 x 0.4 x 0.2 cm. There is a tan-white nodule measuring 1 x 0.6 x 0.4 cm. bisected. AS-1.
- C. Received in formalin labeled "node level 11" and consists of a piece of black soft tissue measuring 0.5 cm. in greatest dimension. AS-1.
- D. Received in formalin labeled "node 4R" and consists of three pieces of tan and red, rubbery soft tissue measuring

GROSS DESCRIPTION

- 1.5 x 2 x 0.5 cm. in aggregate. AS-2.
- E. Received in formalin labeled "right fat pad" and consists of three pieces of tan and red rubbery tissue measuring 1.7 x 1.5 x 0.3 cm. AS-1.
- F. Received in formalin labeled "node level 7" and consists of four pieces of pink and black soft tissue measuring 1.5 cm. in greatest aggregate dimension. AS-1.

[page 2 of 3]
MICROSCOPIC DESCRIPTION

A.

Tumor type: Adenocarcinoma.

Tumor grade: 2-3 out of 3.

Mitotic Index: 2 mitoses/10 HPFs (1 HPF = 0.19 sq mm)

Tumor size: 3.7 x 2.4 x 2.4 cm.

Bronchial resection margin: Negative for malignancy.

Pulmonary margin of resection: Negative for malignancy.

Pleura: Carcinoma invades into the visceral pleura on elastic stain

Vascular invasion: Absent.

Attached lymph nodes: There is no evidence of malignancy in a single peribronchial lymph node.

pTNM Stage: T2 N0.

Non-tumorous lung: There is adjacent bronchiolitis obliterans, endogenous lipoid pneumonia and acute bronchopneumonia. The tumor has a central scar with elastosis and necrosis. There is focal DIP-like change

that

might represent respiratory bronchiolitis away from the tumor.

B. Sections of the nodule show elastosis and chronic inflammation.

MICROSCOPIC DESCRIPTION

C. A single lymph node is negative for malignancy.

D. There is no evidence of malignancy in any of three lymph nodes.

lymph

E. There is no evidence of malignancy in any of four nodes.

lymph

F. There is no evidence of malignancy in any of four nodes.

4x3, 3x2, 14, 15, 18

[page 3 of 3]
DIAGNOSIS

- A. Lung, right upper lobe, resection:
Moderately to poorly-differentiated adenocarcinoma.
- B. Lung, right middle lobe nodule, excisional biopsy:
Elastosis and chronic inflammation. Negative for malignancy.
- C. Lymph nodes, level 11, biopsy:
A single lymph node is negative for malignancy.
- D. Lymph node, 4R, biopsy:
There is no evidence of malignancy in any of three lymph nodes.
- E. Lymph nodes, 2R fat pad, biopsy:
There is no evidence of malignancy in any of four lymph nodes.
- F. Lymph nodes, level 7, biopsy:
There is no evidence of malignancy in any of four lymph nodes.
-

Source: NCI Genomic Data Commons file 299c1053-e63a-4969-91ec-c3f3895af501 (TCGA-44-2668.D5EBAEC8-79C6-493B-AE2A-BBC96E6E5DDC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).